Gene-level copy-number profile of tumor specimen TCGA-EK-A3GN-01A from TCGA case TCGA-EK-A3GN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 47.7 years (17,425 days).
Specimen TCGA-EK-A3GN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.c2ce8955-a17a-44aa-851a-b17941b9987c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A3GN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d52b567-f6ee-4770-8754-b0d62715ee32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 3,131; copy number 2: 43,151; copy number 3: 8,090; copy number 4: 4,624; copy number 7: 87; copy number 8: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A3GN-01A-11D-A20T-01): tumor purity 0.7, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,346,776–204,369,719, 2 genes: AL592114.1, LINC00628.
- chr1:204,394,541–204,394,774, 1 gene: AL606489.2.
- chr22:45,920,366–46,537,620, 23 genes (within-gene range 0–2): WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 797 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr19:9,100,407–10,503,558, 87 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
